Gene-level copy-number profile of tumor specimen TCGA-GN-A26C-01A from TCGA case TCGA-GN-A26C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.8 years (28,427 days).
Specimen TCGA-GN-A26C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.0c7ffeb1-3a11-4958-9bd3-d2f17627ee7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A26C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/242f145b-2e65-4586-b9e0-3835c1904926

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 2: 4,043; copy number 3: 437; copy number 4: 31,953; copy number 5: 366; copy number 6: 12,496; copy number 7: 1,522; copy number 8: 6,604; copy number 9: 1,908; copy number 10: 134; copy number 11: 329.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A26C-01A-11D-A192-01): tumor purity 0.38, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,371 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–89,632,916, 2,237 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr1:115,856,910–121,580,524, 134 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
